Gene-level copy-number profile of tumor specimen TCGA-F4-6569-01A from TCGA case TCGA-F4-6569, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.8 years (22,203 days).
Specimen TCGA-F4-6569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c9040eda-d8ea-48ce-9894-55902b9a0157.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F4-6569-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13489526-1acd-49e0-8786-bc95e47a2b9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,060; copy number 2: 44,753; copy number 3: 8,573; copy number 4: 2,406; copy number 5: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F4-6569-01A-11D-1770-01): tumor purity 0.4, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–786,475, 22 genes, copy number 5 (within-gene range 3–5): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5.

Autosomal genes at a single copy (total copy number 1): 1,673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
